Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAF2, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAF2-01A (Primary Tumor).

ICD-O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
QW 2/3/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 4 cm; tumor confined to testis in available slides; no angio-invasion present; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file cc0aa935-0ee7-41da-a15c-0373ab8d0019 (TCGA-2G-AAF2-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).